Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RM, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RM-01A (Primary Tumor).

[page 1 of 4]
ICD-3

Carcinosa, Mixed
Mullerian Tumor, malignant
8950/3

Site: Endometrium
C54.1

GW 4/2/13

Specimens Submitted:

- 1: SP: UTERUS, CERVIX, RIGHT OVARY AND FALLOPIAN TUBE, AND "BLADDER SEROSA TUMOR;" TOTAL HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY
- 2: SP: Omental nodule (fs)
- 3: SP: Left tube and ovary
- 4: SP: Left infundibulopelvic ligament
- 5: SP: Left sentinel common iliac lymph node
- 6: SP: Cul-de-sac tumor
- 7: SP: Rectal implant
- 8: SP: Left periureteral tumor
- 9: SP: Left external iliac lymph node
- 10: SP: Left hypogastric lymph node
- 11: SP: Left obturator lymph node
- 12: SP: Right obturator lymph node
- 13: SP: Right external iliac lymph node
- 14: SP: Right hypogastric lymph node
- 15: SP: Omentum
- 16: SP: Left para-aortic lymph node
- 17: SP: Right para-aortic lymph node
- 18: SP: Right common iliac lymph node

DIAGNOSIS:

1. SP: UTERUS, CERVIX, RIGHT OVARY AND FALLOPIAN TUBE, AND "BLADDER SEROSA TUMOR;" TOTAL HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY:

Tumor Type:

Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium with heterologous differentiation

Heterologous differentiation (rhabdomyoblasts)

Myometrial Invasion:

(= < 50%)

Measures 6mm in maximum depth

Myometrium thickness measures 15mm in the area of maximal tumor invasion

Tumor nodules are present on anterior the uterine serosa

Endocervical Invasion:

Not identified

** Continued on next page **

[page 2 of 4]
[REDACTED]

Lymphovascular invasion:

Not identified

Endometrium:

Exhibits atrophy

Myometrium:

Exhibits multiple leiomyomata

Adnexa:

Right ovary and fallopian tube; for left adnexa see part 3

2. OMENTAL NODULE; BIOPSY (FS):
-METASTATIC CARCINOSARCOMA
3. OVARY AND FALLOPIAN TUBE, LEFT; SALPINGO-OOPHORECTOMY:
-OVARY WITH MUCINOUS CYSTADENOMA
-BENIGN FALLOPIAN TUBE
4. INFUNDIBULOPELVIC LIGAMENT, LEFT; BIOPSY:
-BENIGN FIBROADIPOSE TISSUE
5. SENTINEL LYMPH NODE, COMMON ILIAC, LEFT; EXCISION:
- THREE BENIGN LYMPH NODES (0/3)
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS
WILL BE REPORTED IN AN ADDENDUM.
6. CUL-DE-SAC TUMOR; BIOPSY:
-SEROSAL IMPLANT OF METASTATIC CARCINOSARCOMA
-BENIGN BLADDER MUCOSA
7. RECTAL IMPLANT; BIOPSY:
-METASTATIC CARCINOSARCOMA
8. PERIURETERAL, LEFT; BIOPSY:
- METASTATIC CARCINOSARCOMA
9. LYMPH NODE, EXTERNAL ILIAC, LEFT; EXCISION:
-ONE BENIGN LYMPH NODE (0/1)
10. LYMPH NODE, HYPOGASTRIC, LEFT; EXCISION:
-TWO BENIGN LYMPH NODES (0/2)
11. LYMPH NODE, OBTURATOR, LEFT; EXCISION:
-ONE BENIGN LYMPH NODE (0/1)
12. LYMPH NODE, OBTURATOR, RIGHT; EXCISION:
-THREE BENIGN LYMPH NODES (0/3)
13. LYMPH NODE, EXTERNAL ILIAC, RIGHT; EXCISION:
-THREE BENIGN LYMPH NODES (0/3)
14. LYMPH NODE, HYPOGASTRIC, RIGHT; EXCISION:
TWO BENIGN LYMPH NODES (0/2)

** Continued on next page **

[page 3 of 4]
-
15. OMENTUM; OMENTECTOMY:
-BENIGN FIBROADIPOSE TISSUE
16. LYMPH NODE, PARA-AORTIC, LEFT; EXCISION:
-TWO BENIGN LYMPH NODES (0/2)
17. LYMPH NODE, PARA-AORTIC, RIGHT; EXCISION:
-ONE BENIGN LYMPH NODE (0/1)
18. LYMPH NODE, COMMON ILIAC, RIGHT:
-THREE BENIGN LYMPH NODES (0/3)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 4 of 4]
Procedures/Addenda:
Addendum

Addendum Diagnosis

ADDENDUM REPORT

5. SP: LEFT SENTINEL COMMON ILIAC LYMPH NODE:
ADDITIONAL H/E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR
CYTOKERATINS (AE1:AE3)
SHOW NO EVIDENCE OF METASTATIC TUMOR.

	Yes	No
1. Accuracy		✓
2. Completeness		✓
3. Consistency		✓
4. Timeliness		✓
5. Overall Quality		✓
Signature: [Signature] / Date: 12/31/12		

Source: NCI Genomic Data Commons file 9f77da26-a104-4fc1-b1e9-1b405517b631 (TCGA-N5-A4RM.C188B8E8-B564-45A6-B356-B4D7C64B8DA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).